TCGA case TCGA-MP-A4T8 — Lung Adenocarcinoma (TCGA-LUAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung; Tissue source site: Washington University - Mayo Clinic. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7c4ed533-ee66-48be-a84b-ff8607742818

Demographics
Sex at birth: male; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Dead; Days to death: 161 days.

Diagnoses (3)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 68.6 years (25,069 days); Year of diagnosis: 2006; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Vinorelbine Tartrate; Days to treatment start: 42 days; Days to treatment end: 72 days.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; Age at diagnosis: 68.3 years (24,943 days); Days to diagnosis: -126 days.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: -50 days; Treatment anatomic sites: Locoregional Site.
   Recorded as not given: Pharmaceutical Therapy, NOS; Surgery, NOS.
3. Prior malignancy of the rectum (histology not recorded by GDC).
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Colon.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- ECOG performance status: 1; Timepoint: Prior to Adjuvant Therapy.
- Follow-up contact recording only the day: day 161.

Other clinical attributes
- DLCO (% of predicted): 102; FEV1 after bronchodilator (% of reference): 72; FEV1 before bronchodilator (% of reference): 60.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 25; Tobacco smoking onset year: 1957; Tobacco smoking quit year: 1972.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-MP-A4T8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 130 mg.
  Slide TCGA-MP-A4T8-01A-01-TSA: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 10; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 30.
- Sample TCGA-MP-A4T8-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-MP-A4T8-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Adenocarcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Performance status timing: Pre-Adjuvant Therapy; Tobacco smoking history indicator: 3; Anatomic organ subdivision: L-Upper; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes.
- Drug treatment 1: Pharmaceutical therapy drug name: Navelbine.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Rectum.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Colostomy.
- Other malignancy form 2: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 2, Radiation treatment: Radiation therapy extent: Locoregional; History radiation treatment to site of TCGA tumor: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 161 days; disease-specific survival: event status not recorded, 161 days; progression-free interval: no event (censored), 161 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-MP-A4T8-01A-11D-A24O-01): tumor purity 0.59, ploidy 3.17, whole-genome doublings 1.
